Somatic mutation profile of tumor specimen C3L-00968-04 (aliquot CPT0101710009) from CPTAC case C3L-00968, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 61.9 years (22,612 days).
Specimen C3L-00968-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b62d706-9df8-4af8-bda4-00e00fa3dda1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00968-31 (Blood Derived Normal), aliquot CPT0100990002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/341c7875-9032-4e11-9f6d-b8c7edc06994

The open-access MAF lists 110 somatic variants for this specimen: 76 protein-altering or splice-affecting, 20 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 20, Intron 9, Frame Shift Ins 6, Frame Shift Del 5, Nonsense Mutation 4, Nonstop Mutation 2, Splice Site 2, In Frame Del 2, RNA 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC25A19 | c.775-1G>C p.X259_splice | Splice Site (SNP) | VAF 27/271 reads (10%) | catalogued as rs372041843; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM2A | c.256C>A p.L86M (on ENST00000219054; = p.L7M on NM_001308169.2) | Missense Mutation (SNP) | VAF 58/312 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as rs781233119; called by muse, varscan2
- AMPH | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs764013614, COSV100342559; called by muse, mutect2, varscan2
- C5orf51 | c.456G>A p.W152* | Nonsense Mutation (SNP) | VAF 128/280 reads (46%) | catalogued as COSV67565930; called by muse, mutect2, varscan2
- CCDC42 | c.55T>C p.Y19H | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs750526989; called by muse, mutect2, varscan2
- CCDC78 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.155); catalogued as rs201634385; called by muse, mutect2, varscan2
- CCT6A | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs770231271, COSV51904316; called by muse, mutect2, varscan2
- DYNC2I1 | c.251G>A p.R84K | Missense Mutation (SNP) | VAF 108/333 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as COSV68106773; called by muse, mutect2, varscan2
- ERMP1 | c.1951dup p.T651Nfs*25 | Frame Shift Ins (INS) | VAF 22/112 reads (20%) | catalogued as rs753821453; called by mutect2, varscan2
- F5 | c.1846G>T p.G616W | Missense Mutation (SNP) | VAF 118/598 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889063, COSV63124812; called by muse, mutect2, varscan2
- GABRA5 | c.183C>G p.D61E | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59482616; called by muse, mutect2, varscan2
- KRT36 | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 122/417 reads (29%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.564); catalogued as COSV60203957; called by muse, mutect2, varscan2
- KRT6A | c.818A>G p.D273G | Missense Mutation (SNP) | VAF 136/534 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs759876129; called by muse, mutect2, varscan2
- KRTAP11-1 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 115/338 reads (34%) | SIFT tolerated (0.96); PolyPhen benign (0.119); catalogued as rs1417279055; called by muse, mutect2
- MDGA2 | c.1889G>T p.C630F (on ENST00000399232 / NM_001113498.2; = p.C332F on NM_182830.4) | Missense Mutation (SNP) | VAF 113/372 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV99050706; called by muse, mutect2, varscan2
- NID1 | c.1391T>C p.M464T | Missense Mutation (SNP) | VAF 182/420 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.841); catalogued as rs756367830; called by muse, mutect2, varscan2
- PHRF1 | c.4147C>T p.R1383W (on ENST00000264555 / NM_001286581.2; = p.R1382W on NM_020901.4) | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs375620742; called by muse, mutect2, varscan2
- PID1 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.791); catalogued as rs771130057; called by muse, mutect2, varscan2
- SORL1 | c.4706G>A p.G1569E | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52749313; called by muse, mutect2, varscan2
- TMEM132E | c.985G>C p.G329R (on ENST00000321639; = p.G419R on NM_001304438.2) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV58697197, COSV58697738; called by muse, mutect2, varscan2
- WDR81 | c.3922G>T p.E1308* (on ENST00000409644 / NM_001163809.2; = p.E257* on NM_152348.4) | Nonsense Mutation (SNP) | VAF 53/169 reads (31%) | catalogued as COSV58481395; called by muse, mutect2, varscan2
- ABCA9 | c.2783dup p.N928Kfs*21 | Frame Shift Ins (INS) | VAF 45/187 reads (24%) | called by mutect2, pindel, varscan2
- ACTN2 | c.2066A>C p.K689T | Missense Mutation (SNP) | VAF 161/627 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAM29 | c.1087A>G p.I363V | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADAMTS12 | c.3989G>A p.G1330D | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFF4 | c.2639_2644del p.E880_K881del | In Frame Del (DEL) | VAF 84/206 reads (41%) | called by mutect2, pindel, varscan2
- AP3M2 | c.1014G>A p.M338I | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFGEF2 | c.2245T>C p.F749L | Missense Mutation (SNP) | VAF 139/496 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ATE1 | c.851dup p.K285Qfs*12 | Frame Shift Ins (INS) | VAF 46/196 reads (23%) | called by mutect2, pindel, varscan2
- CISD1 | c.158dup p.N53Kfs*9 | Frame Shift Ins (INS) | VAF 36/129 reads (28%) | called by mutect2, pindel, varscan2
- COL4A3 | c.2717C>T p.P906L | Missense Mutation (SNP) | VAF 86/305 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.602); called by muse, varscan2
- CPN1 | c.1334dup p.K446Efs*64 | Frame Shift Ins (INS) | VAF 98/426 reads (23%) | called by pindel, varscan2
- DENND4B | c.3236C>T p.P1079L | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DGCR2 | c.1197dup p.D400* | Frame Shift Ins (INS) | VAF 56/147 reads (38%) | called by mutect2, pindel, varscan2
- DYRK3 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 196/421 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- ELOA2 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 97/479 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- FANCD2 | c.1561C>A p.L521M | Missense Mutation (SNP) | VAF 112/281 reads (40%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- GPT2 | c.697T>G p.Y233D | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSK3A | c.230G>A p.S77N | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPA5 | c.1888A>T p.I630F | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- KANK1 | c.3717G>C p.M1239I | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- KIF16B | c.2903A>C p.K968T | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- KLHDC1 | c.525A>G p.I175M | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MAGI1 | c.2933_2936del p.N978Rfs*11 (on ENST00000402939 / NM_001033057.2; = p.N1006Rfs*11 on NM_004742.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 79/169 reads (47%) | called by mutect2, pindel, varscan2
- MEX3B | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NCKAP1 | c.2854A>G p.M952V | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NF2 | c.458dup p.Y153* | Nonsense Mutation (INS) | VAF 91/230 reads (40%) | called by mutect2, pindel, varscan2
- NSUN7 | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- NSUN7 | c.1700C>G p.A567G | Missense Mutation (SNP) | VAF 101/253 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- OR2AT4 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 78/249 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- OR5T1 | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ORAI1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- OTOGL | c.6466A>G p.T2156A (on ENST00000547103; = p.T2147A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OTUB1 | c.137C>G p.P46R | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- PKD1 | c.11006G>T p.G3669V (on ENST00000262304 / NM_001009944.3; = p.G3668V on NM_000296.4) | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PLEC | c.8282A>T p.K2761M (on ENST00000322810 / NM_201380.4; = p.K2651M on NM_000445.5) | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- PLPPR3 | c.1747A>T p.I583F (on ENST00000520876 / NM_001270366.2; = p.I611F on NM_024888.2) | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- PRR13 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRUNE2 | c.7146del p.D2383Ifs*3 | Frame Shift Del (DEL) | VAF 95/233 reads (41%) | called by mutect2, pindel, varscan2
- RHBDF2 | c.2478C>A p.Y826* | Nonsense Mutation (SNP) | VAF 55/203 reads (27%) | called by muse, mutect2, varscan2
- RHOXF2B | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.543); called by muse, mutect2
- SCN8A | c.5380_5382del p.K1794del | In Frame Del (DEL) | VAF 55/187 reads (29%) | called by mutect2, pindel, varscan2
- SCYL2 | c.500T>A p.F167Y | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD2 | c.5142+1G>T p.X1714_splice | Splice Site (SNP) | VAF 41/89 reads (46%) | called by muse, mutect2, varscan2
- SIX4 | c.1428_1441del p.Q477Wfs*16 | Frame Shift Del (DEL) | VAF 34/256 reads (13%) | called by mutect2, pindel, varscan2
- SNAPC1 | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.741); called by muse, varscan2
- SNX6 | c.182C>T p.T61I (on ENST00000652385; = p.T49I on NM_152233.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRSF7 | c.717A>G p.*239Wext*21 | Nonstop Mutation (SNP) | VAF 39/152 reads (26%) | called by muse, mutect2, varscan2
- SYNE1 | c.4513G>A p.E1505K (on ENST00000367255 / NM_182961.4; = p.E1512K on NM_033071.3) | Missense Mutation (SNP) | VAF 169/459 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- TES | c.699del p.Q233Hfs*9 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | called by mutect2, pindel, varscan2
- TET1 | c.4587G>A p.M1529I | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- VPS51 | c.2347T>C p.*783Qext*? | Nonstop Mutation (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
- YDJC | c.43T>A p.F15I | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ZNF138 | c.471C>G p.H157Q (on ENST00000307355 / NM_001367572.1; = p.H131Q on NM_006524.4) | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF221 | c.425A>T p.N142I | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- ZNF614 | c.708del p.Q236Hfs*15 | Frame Shift Del (DEL) | VAF 88/269 reads (33%) | called by mutect2, pindel, varscan2
- ACACA | c.5409T>C p.S1803= | Silent (SNP) | VAF 88/287 reads (31%) | called by muse, mutect2, varscan2
- ACE | c.2604C>T p.H868= | Silent (SNP) | VAF 95/316 reads (30%) | catalogued as rs753727679, COSV52010147; called by muse, mutect2, varscan2
- ACTG1 | c.897G>T p.L299= | Silent (SNP) | VAF 157/534 reads (29%) | called by muse, mutect2, varscan2
- ADGRG1 | c.1444C>T p.L482= | Silent (SNP) | VAF 125/458 reads (27%) | called by muse, mutect2, varscan2
- CWF19L1 | c.804A>G p.K268= | Silent (SNP) | VAF 35/145 reads (24%) | called by muse, mutect2, varscan2
- DNAH2 | c.12816G>C p.R4272= | Silent (SNP) | VAF 111/382 reads (29%) | called by muse, mutect2, varscan2
- DPYSL3 | c.753C>T p.Y251= | Silent (SNP) | VAF 36/155 reads (23%) | catalogued as rs768834528, COSV58328072; called by muse, mutect2, varscan2
- MGA | c.8874C>A p.P2958= (on ENST00000219905 / NM_001164273.1; = p.P2749= on NM_001080541.2) | Silent (SNP) | VAF 82/180 reads (46%) | called by muse, mutect2, varscan2
- NFASC | c.120G>A p.P40= (on ENST00000339876 / NM_001378329.1; = p.P34= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/230 reads (22%) | catalogued as rs141859066; called by muse, mutect2, varscan2
- PLBD1 | c.1461A>T p.G487= | Silent (SNP) | VAF 43/155 reads (28%) | called by muse, mutect2, varscan2
- RAB36 | c.519C>T p.S173= | Silent (SNP) | VAF 57/119 reads (48%) | catalogued as rs1221408389; called by muse, mutect2, varscan2
- SESN3 | c.402G>A p.K134= | Silent (SNP) | VAF 52/176 reads (30%) | called by muse, varscan2
- SLC29A3 | c.127C>T p.L43= | Silent (SNP) | VAF 137/424 reads (32%) | catalogued as rs1322399308; called by muse, mutect2, varscan2
- SLC34A1 | c.87T>C p.F29= | Silent (SNP) | VAF 121/537 reads (23%) | called by muse, mutect2, varscan2
- SPICE1 | c.822T>A p.T274= | Silent (SNP) | VAF 58/271 reads (21%) | called by muse, mutect2, varscan2
- SRCAP | c.8565T>C p.A2855= | Silent (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- THBD | c.6T>A p.L2= | Silent (SNP) | VAF 31/122 reads (25%) | called by muse, mutect2, varscan2
- TRRAP | c.2592C>T p.H864= | Silent (SNP) | VAF 57/177 reads (32%) | catalogued as COSV100722630; called by muse, mutect2, varscan2
- ULK4 | c.2427C>T p.H809= | Silent (SNP) | VAF 52/105 reads (50%) | called by muse, mutect2, varscan2
- ZBTB22 | c.1524C>A p.L508= | Silent (SNP) | VAF 79/261 reads (30%) | catalogued as COSV99801544; called by muse, mutect2, varscan2
- CACNA1D | c.4924-3904del | Intron (DEL) | VAF 42/110 reads (38%) | called by mutect2, pindel, varscan2
- GPN3 | c.48+9C>A | Intron (SNP) | VAF 127/395 reads (32%) | called by muse, mutect2, varscan2
- GUSB | c.913-21C>T | Intron (SNP) | VAF 107/359 reads (30%) | called by muse, mutect2, varscan2
- LILRB5 | c.1255+46A>C | Intron (SNP) | VAF 30/109 reads (28%) | called by muse, mutect2, varscan2
- LINGO1-AS1 | n.384_385insTTT | RNA (INS) | VAF 49/131 reads (37%) | called by mutect2, pindel, varscan2
- LRRC37BP1 | chr17:30631938 C>G | 5'Flank (SNP) | VAF 85/277 reads (31%) | called by muse, mutect2, varscan2
- MCOLN1 | c.680+85del | Intron (DEL) | VAF 69/227 reads (30%) | called by mutect2, pindel, varscan2
- MOB4 | c.60+508T>C | Intron (SNP) | VAF 58/226 reads (26%) | called by muse, mutect2, varscan2
- RBBP4 | c.-49C>A | 5'UTR (SNP) | VAF 42/65 reads (65%) | called by muse, mutect2, varscan2
- SNORD3B-2 | n.37T>C | RNA (SNP) | VAF 32/326 reads (10%) | catalogued as rs1242543220; called by muse, varscan2
- TM4SF18 | c.*36C>T | 3'UTR (SNP) | VAF 36/120 reads (30%) | called by muse, mutect2, varscan2
- ZNF195 | c.226+3989C>T | Intron (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- ZNF195 | c.226+3988G>T | Intron (SNP) | VAF 27/96 reads (28%) | called by muse, mutect2, varscan2
- ZNF846 | c.15+36G>T | Intron (SNP) | VAF 60/211 reads (28%) | catalogued as rs549024276; called by muse, mutect2, varscan2
